Somatic mutation profile of tumor specimen TCGA-JV-A5VF-01A (aliquot TCGA-JV-A5VF-01A-11D-A29N-09) from TCGA case TCGA-JV-A5VF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 69.8 years (25,505 days).
Specimen TCGA-JV-A5VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 760cf9da-8411-42ec-b367-9d6ac916f8dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JV-A5VF-10A (Blood Derived Normal), aliquot TCGA-JV-A5VF-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af039f62-a602-4f65-9e76-cf89331b416c

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Silent 4, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 24/32 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469672, COSV61329296, COSV61329353, COSV61329428; ClinVar: other / not provided; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 61/65 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAG6 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52988628; called by muse, mutect2, varscan2
- CCDC91 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100081795; called by muse, mutect2, varscan2
- CD276 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs537842985, COSV100573361; called by muse, mutect2
- COL4A6 | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564072; called by muse, mutect2, varscan2
- HCK | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145632103; called by muse, mutect2, varscan2
- HS3ST3A1 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99404255; called by muse, mutect2, varscan2
- KALRN | c.5924T>A p.V1975E (on ENST00000360013 / NM_001024660.4; = p.V278E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99362013; called by muse, mutect2, varscan2
- MAGEL2 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs866333931, COSV100045920; called by muse, mutect2, varscan2
- NOS1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100500565; called by muse, mutect2, varscan2
- OR1S2 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100224178; called by muse, mutect2, varscan2
- PHF24 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781633965, COSV54274878; called by muse, mutect2, varscan2
- PRSS53 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs1441646116, COSV99762289; called by muse, mutect2, varscan2
- SHROOM2 | c.3734A>T p.D1245V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101098554; called by muse, mutect2, varscan2
- SMARCAL1 | c.2408A>G p.E803G | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619882; called by muse, mutect2, varscan2
- SNX6 | c.1069C>A p.Q357K (on ENST00000652385; = p.Q229K on NM_021249.5) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV100751481; called by muse, mutect2, varscan2
- SULT1B1 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100150251; called by muse, mutect2, varscan2
- TIE1 | c.2384G>C p.R795P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV100992075; called by muse, varscan2
- VCPIP1 | c.1949C>G p.T650S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV100125585; called by muse, mutect2, varscan2
- VPS16 | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100988481; called by muse, mutect2, varscan2
- ZNF175 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99219473; called by muse, mutect2, varscan2
- ZNF337 | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 39/85 reads (46%) | catalogued as COSV99430181; called by muse, mutect2, varscan2
- DPM3 | c.117_135del p.W39Cfs*41 (on ENST00000341298; = p.W69Cfs*41 on NM_018973.3) | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- PRIM2 | c.470_492del p.E157Gfs*13 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2942A>G p.E981G | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- TEP1 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); called by muse, mutect2
- TNR | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- HSPA6 | c.517C>A p.R173= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100554133; called by muse, mutect2, varscan2
- IFNE | c.318G>A p.T106= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs913875748, COSV58643043; called by muse, mutect2, varscan2
- OR1S2 | c.972C>G p.S324= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100224176; called by muse, mutect2, varscan2
- PTCRA | c.432G>A p.P144= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs753917737, COSV100485748; called by muse, mutect2, varscan2
